Gene-level copy-number profile of tumor specimen MP2PRT-PASTMJ-TMP1-A from MP2PRT case MP2PRT-PASTMJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,382 days).
Specimen MP2PRT-PASTMJ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9865a302-94f6-49f9-aab7-98e7d8ff92b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASTMJ-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/69296a94-6bf9-4269-b825-486c4a0d9496

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 76; copy number 1: 3,057; copy number 2: 55,759; copy number 3: 7.

Homozygous deletions (total copy number 0; autosomes only): 76 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,861,886–88,992,931, 10 genes (within-gene range 0–1): IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8.
- chr2:89,027,171–89,027,731, 1 gene (within-gene range 0–1): IGKV3-11.
- chr2:89,134,975–89,172,553, 5 genes (within-gene range 0–1): IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23.
- chr2:89,203,509–89,295,455, 11 genes (within-gene range 0–1): AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32, IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36.
- chr14:105,881,034–106,005,574, 35 genes (within-gene range 0–1): IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3.
- chr22:22,834,865–22,886,379, 9 genes (within-gene range 0–1): AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571.
- chr22:22,893,692–22,905,025, 5 genes (within-gene range 0–1): IGLJ1, IGLC1, IGLJ2, IGLC2, IGLJ3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 201. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
